Gene-level copy-number profile of tumor specimen TCGA-B6-A0WY-01A from TCGA case TCGA-B6-A0WY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40.5 years (14,778 days).
Specimen TCGA-B6-A0WY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2e1d7b07-9e79-47b6-98c2-d5966f1760d2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0WY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/063cd2d3-cdf8-469a-842f-0062fe0e714b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,378; copy number 2: 20,317; copy number 3: 15,262; copy number 4: 17,761; copy number 5: 1,843; copy number 6: 1,028; copy number 7: 1,372; copy number 8: 787; copy number 11: 55; copy number 14: 3; copy number 28: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0WY-01A-11D-A107-01): tumor purity 0.25, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,102 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,864,773–198,222,513, 605 genes, copy number 7 (broad region; genes not listed).
- chr5:30,248,350–30,693,984, 3 genes, copy number 5 (within-gene range 4–5): HPRT1P2, AC114300.1, AC099517.1.
- chr8:37,597,480–37,899,497, 14 genes, copy number 28 (within-gene range 1–28): AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1.
- chr8:43,672,823–145,066,685, 1,536 genes, copy number 7–8 (broad region; genes not listed).
- chr11:65,615,773–94,549,898, 781 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:96,341,438–96,514,748, 6 genes, copy number 5: MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737.
- chr11:96,642,671–96,643,225, 1 gene, copy number 5: AP003066.2.
- chr11:97,222,644–100,358,885, 10 genes, copy number 6 (within-gene range 2–6): LINC02553, RNA5SP347, LINC02713, AP003730.1, AP001317.1, AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53.
- chr19:9,604,680–9,849,689, 18 genes, copy number 11–14 (within-gene range 5–14): ZNF561, ZNF561-AS1, ZNF562, RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1.
- chr19:10,251,901–40,765,389, 1,246 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr20:33,912,323–64,313,132, 782 genes, copy number 6 (broad region; genes not listed).
- chr21:19,130,523–19,760,128, 8 genes, copy number 6: AP000431.1, SLC6A6P1, AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1.
- chr21:46,185,079–46,665,124, 18 genes, copy number 7: AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.
- chr22:33,704,786–34,218,796, 6 genes, copy number 6 (within-gene range 2–6): SNORA50B, Z69713.1, LARGE-IT1, LARGE-AS1, Z73429.1, LINC01643.
- chr22:49,718,053–50,801,309, 68 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,378. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
